Gene-level copy-number profile of tumor specimen TCGA-26-1442-01A from TCGA case TCGA-26-1442, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.7 years (15,950 days).
Specimen TCGA-26-1442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.bf87e8d4-8eca-49ad-a30a-3668ba22077a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-26-1442-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b56dc0c1-2b9d-479a-aa01-6ca5b7fb69aa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,113; copy number 3: 2,169; copy number 4: 52,872; copy number 6: 199; copy number 9: 56; copy number 11: 410.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-26-1442-01A-01D-1694-01): tumor purity 0.79, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 466 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–12,562,863, 456 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr12:13,196,723–13,982,002, 10 genes, copy number 9 (within-gene range 4–9): EMP1, AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
